Somatic mutation profile of tumor specimen MP2PRT-PARPKB-TMP1-A (aliquot MP2PRT-PARPKB-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARPKB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,328 days).
Specimen MP2PRT-PARPKB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0a7fe45-19e4-4d9d-a511-fd0af1629342.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPKB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPKB-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97d053de-492d-4d4b-9085-12b03cbff7b7

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHST6 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 244/551 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs752453536; called by muse, mutect2, varscan2
- H1-4 | c.111del p.P39Rfs*50 | Frame Shift Del (DEL) | VAF 201/578 reads (35%) | catalogued as rs748723810; called by mutect2, pindel, varscan2
- SLC35F4 | c.821C>T p.T274M (on ENST00000339762 / NM_001352015.2; = p.T238M on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 169/380 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs778823697, COSV60262638; called by muse, mutect2, varscan2
- UNC13C | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 140/318 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs748788123, COSV52884349; called by muse, mutect2, varscan2
- ZNF229 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 139/301 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs367712470; called by muse, mutect2, varscan2
- LRRC9 | c.856A>C p.K286Q | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); called by muse, mutect2
- LRRFIP1 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 141/361 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PDGFRA | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 170/439 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSKH2 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 263/616 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RPH3A | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 15/411 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2
- UBB | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 187/500 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, varscan2
- ADAM23 | c.1623C>T p.S541= | Silent (SNP) | VAF 122/269 reads (45%) | catalogued as rs774008238, COSV52235682; called by muse, mutect2, varscan2
- GALNT7 | c.1701G>A p.G567= | Silent (SNP) | VAF 89/193 reads (46%) | called by muse, mutect2, varscan2
- IL18RAP | c.771C>T p.V257= | Silent (SNP) | VAF 90/202 reads (45%) | catalogued as rs781511048; called by muse, mutect2, varscan2
- KCNQ2 | c.1587C>T p.T529= (on ENST00000359125 / NM_172107.4; = p.T501= on NM_004518.6) | Silent (SNP) | VAF 190/469 reads (41%) | catalogued as rs753417293; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506995 ins CCT | 3'Flank (INS) | VAF 62/152 reads (41%) | called by pindel, varscan2
